Surgical pathology report (de-identified scan), TCGA case TCGA-ZN-A9VQ, project TCGA-MESO (Mesothelioma), tissue source site Brigham and Women's Hospital Division of Thoracic Surgery, specimen TCGA-ZN-A9VQ-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Report Status: Final

Procedure Date:

ICD-O-3

Mesothelioma, lymphatic, malignant
9053/3

Site: Pleura NOS
0384

W 6/18/14

PATHOLOGIC DIAGNOSIS:

A. RIGHT RIB:

Bone marrow with maturing trilineage hematopoiesis,
negative for tumor.

B. LEVEL 9 LYMPH NODE BIOPSY:

Lymph node fragments with calcified nodules, negative
for tumor, see Note.

Gram, fungal (MSS), and acid-fast stains are negative
for organisms.

C. LEVEL 8 LYMPH NODE BIOPSY:

Lymph node fragments with calcified nodules, negative
for tumor, see Note.

Gram, fungal (MSS), and acid-fast stains are negative
for organisms.

D. LEVEL 7 LYMPH NODE BIOPSY:

Lymph node fragments negative for tumor.

E. LEVEL 10R LYMPH NODE BIOPSY:

Lymph node fragments negative for tumor.

F. DIAPHRAGM:

MALIGNANT MESOTHELIOMA epithelioid type invasive in
fibroadipose tissue.
Skeletal muscle and tendon are present and uninvolved.

G. VISCERAL AND PARIETAL PLEURA:

MALIGNANT MESOTHELIOMA mixed epithelioid (90%) and
sarcomatoid (10%) types, invasive in fibroadipose
tissue (multiple nodules up to 6.8 cm), see Note.

Tumor extends to inked pleural surface.

NOTE: Select slides reviewed with

H. PHRENIC NERVE (INCLUDING FSA):

MALIGNANT MESOTHELIOMA epithelioid type invasive in
fibroadipose tissue.

I OLD PORT SITE 1:

Skin and subcutis with chronic inflammation and scar,
negative for tumor.

NOTE: The calcified nodules noted in lymph nodes likely
represent a remote infection. Select slides reviewed
with

[page 2 of 3]
Pathology Report

TISSUE SUBMITTED:

A/1. Right rib.
B/2. Level 9.
C/3. Level 8.
D/4. Level 7.
E/5. Level 10R.
F/6. Diaphragm.
G/7. Visceral and parietal pleura.
H/8. Phrenic nerve (FS).
I/9. Old port site #1.

O.R. CONSULTATION:

SPECIMEN LABELED "#8 PHRENIC NODULE" (FSA):

Epithelioid mesothelioma, invasive in fibrous tissue.

OR Consultation by:

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnosis(es) related thereto.

GROSS DESCRIPTION:

The specimen is received fresh, in nine parts, each labeled with the patient's name and medical record number.

Part A, "#1. Right rib", consists of four segments of rib (12.0, 5.8, 1.2, and 2.5 cm in length x an average diameter of 2.2 cm). Scant attached tan/red skeletal muscle and tan/red fibrous tissue is present. There is no gross evidence of involvement by tumor. A bone marrow squeeze is performed.

Micro A1: Bone marrow squeeze, multi frags, RSS.

Part B, "#2. Level 9", consists of four fragments of tan/red fibrous tissue, tan/yellow adipose tissue and focally anthracotic tan/red lymph node candidates (3.6 x 1.5 x 1.2 cm in aggregate). One fragment exhibits a firm tan/yellow cut surface. The specimen is entirely submitted for microscopic examination.

Micro B1-B3: Soft tissue fragments, multi frags, ESS.

Part C, "#3. Level 8", consists of a single tan/white to tan/red focally anthracotic soft tissue fragment consistent with lymph node (1.2 x 0.8 x 0.5 cm). The specimen is bisected and entirely submitted for microscopic examination.

Micro C1: Soft tissue fragment, 2 frags, ESS.

Part D, "#4. Level 7", consists of six fragments of tan/white to tan/red soft tissue with focal anthracosis, consistent with lymph node candidates (3.9 x 2.1 x 0.6 cm). The specimen is entirely submitted for microscopic examination.

Micro D1 through D2: Soft tissue fragments, multi frags, ESS.

Part E, "#5. Level 10R", consists of a single tan/red to tan/white focally anthracotic soft tissue fragment (0.6 x 0.3 x 0.2 cm). The specimen is entirely submitted for microscopic examination.

[page 3 of 3]
Pathology Report

Micro E1: Soft tissue fragment, 1 frag, ESS.

Part F, "#6. Diaphragm", consists of three fragments of tan/red skeletal muscle and tan/red soft tissue focally lined by a smooth and glistening surface (5.6 x 3.5 x 1.4 cm in aggregate). Multiple (at least 10) tan/white firm nodules (up to 0.2 cm in maximum dimension) are present on the soft tissue overlying the skeletal muscle. No definitive involvement of skeletal muscle by tumor is identified. Representative sections are submitted.

Micro F1 through F2: Representative sections of soft tissue and skeletal muscle, 3 frags each, RSS.

Part G, "#7. Visceral and parietal pleura", consists of a 388.0 gram aggregate of tan/pink fibromembranous soft tissue (29.0 x 24.0 x 3.8 cm in aggregate) with multiple (at least 100) tan/pink nodules (ranging from 0.2 to 6.8 cm) and admixed tan/yellow lobulated adipose tissue. Representative sections of the nodules are submitted to the

The surface overlying the nodules is focally inked black and Representative sections are submitted for permanent microscopic examination.

Micro G1 through G4: Sections of largest nodules, 1-3 frags each, RSS.

Part H, "#8. Phrenic nerve", consists of a single irregular yellow/pink soft tissue fragment (1.2 x 1.0 x 0.5 cm). The specimen is inked black, bisected and entirely submitted for frozen section examination as FSA.

Micro H1: Frozen section remnant (FSA), 2 frags, ESS.

Part I, "#9. Old port site #1", consists of a single fragment of tan/white skin and subcutis (2.1 x 0.5 cm, extending to a depth of 2.2 cm). The subcutis is firm with abundant tan/white fibrous scar tissue, but no focal mass lesions are identified. The specimen is entirely submitted for microscopic examination.

Micro I1 through I2: Skin and subcutis, 1-2 frags each, ESS.

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file 3c43c232-5514-427c-8647-c8ac9cbd1cf6 (TCGA-ZN-A9VQ.9FAAD3FA-195F-48A3-A09C-603C8635990A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).